Somatic mutation profile of tumor specimen C3N-00433-03 (aliquot CPT0021450009) from CPTAC case C3N-00433, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 57.8 years (21,129 days).
Specimen C3N-00433-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6925d2c2-cd11-47fc-b706-d737dbf8c086.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00433-71 (Blood Derived Normal), aliquot CPT0021500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b005c77-1d20-4ca7-a6fe-da4c2887813a

The open-access MAF lists 196 somatic variants for this specimen: 130 protein-altering or splice-affecting, 42 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 42, Nonsense Mutation 12, Intron 9, RNA 4, Splice Site 3, 3'UTR 3, 5'UTR 3, 5'Flank 3, Frame Shift Del 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 29/276 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 10/211 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2
- ADCY9 | c.3648G>C p.L1216F | Missense Mutation (SNP) | VAF 31/539 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53570724, COSV53573113; called by muse, mutect2
- ADGRB1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.505); catalogued as rs1266484333, COSV60098719; called by muse, mutect2
- ARHGEF10 | c.145G>C p.E49Q (on ENST00000398564; = p.E25Q on NM_014629.4) | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as rs527779906; called by muse, mutect2
- CAPN11 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs201179894; called by muse, mutect2, varscan2
- CLIP2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1554732676; called by muse, mutect2
- CLPTM1 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV61610861; called by muse, mutect2
- CNTN2 | c.2470G>T p.V824F | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs879704414; called by muse, mutect2
- CYP46A1 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.21); catalogued as COSV55896830; called by muse, mutect2
- DOK5 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | catalogued as rs1330673551; called by muse, mutect2
- EEPD1 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 38/514 reads (7%) | catalogued as rs1385942638; called by muse, mutect2
- ELMO1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs779233099; called by muse, mutect2
- EMP2 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.158); catalogued as rs1452297350, COSV100852878, COSV63995874; called by muse, mutect2
- FANCI | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 9/287 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV55525162; called by muse, mutect2
- GDF15 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV53251545; called by muse, mutect2
- HARS1 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV56905582, COSV56906207; called by muse, mutect2
- HTR3D | c.890T>A p.L297Q | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV61915405; called by muse, mutect2
- KAT6B | c.5242G>A p.V1748I | Missense Mutation (SNP) | VAF 21/564 reads (4%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.168); catalogued as rs774598396, COSV54745257; called by muse, mutect2
- KCNK2 | c.935G>T p.R312L (on ENST00000444842 / NM_001017425.3; = p.R297L on NM_014217.4) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV67206017; called by muse, mutect2
- KDM6A | c.3657G>C p.W1219C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100938337, COSV65042442, COSV65048736; called by muse, mutect2
- LIN37 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.06); catalogued as COSV50001554; called by muse, mutect2, varscan2
- LMX1A | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV54226651; called by muse, mutect2
- METTL24 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); catalogued as COSV58822040; called by muse, mutect2
- MXRA5 | c.6386G>T p.G2129V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs753446720; called by muse, mutect2, varscan2
- MYH4 | c.3057C>A p.D1019E | Missense Mutation (SNP) | VAF 18/620 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs1362801931; called by muse, mutect2
- MYH9 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53391283; called by muse, mutect2
- NFE2L3 | c.1779G>C p.Q593H | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760726955; called by muse, mutect2, varscan2
- NLRP5 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759531334, COSV66767431; called by muse, mutect2
- NOTCH4 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 23/583 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV66679387; called by muse, mutect2
- OR8H2 | c.759C>A p.S253R | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57944831; called by muse, mutect2
- OTOG | c.8667C>A p.C2889* | Nonsense Mutation (SNP) | VAF 42/762 reads (6%) | catalogued as COSV68039720; called by muse, mutect2
- PNPLA4 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs777194837; called by muse, mutect2
- PTPRT | c.1001G>T p.W334L | Missense Mutation (SNP) | VAF 37/667 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100626118, COSV61966932; called by muse, mutect2
- RAI1 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as rs1203319767; called by muse, mutect2
- SCN10A | c.2388C>G p.I796M | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1327785311; called by muse, mutect2
- SDK2 | c.5513C>A p.S1838Y | Missense Mutation (SNP) | VAF 18/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101167655, COSV66181636; called by muse, mutect2
- SETD2 | c.4471C>G p.H1491D | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57445513; called by muse, mutect2
- SPATA31E1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as rs1159839916; called by muse, mutect2
- TNN | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 43/647 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.182); catalogued as rs147066934, COSV53421267; called by muse, mutect2
- TSSK1B | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs770706524, COSV66814886; called by muse, mutect2
- USP31 | c.3161C>G p.S1054* | Nonsense Mutation (SNP) | VAF 11/188 reads (6%) | catalogued as COSV99565904; called by muse, mutect2
- VEGFC | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV54604920; called by muse, mutect2
- XKR7 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.215); catalogued as COSV73813162; called by muse, mutect2
- ZFHX4 | c.7533C>A p.H2511Q | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51437699; called by muse, mutect2
- ACACA | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 25/564 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ACTN2 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 32/788 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ADAMTS7 | c.2267A>T p.Q756L | Missense Mutation (SNP) | VAF 42/827 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ARMCX5-GPRASP2 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ARSH | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS9 | c.2074C>A p.L692I (on ENST00000242067 / NM_001348036.1; = p.L652I on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCORL1 | c.1069A>T p.M357L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD8 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2
- CCDC40 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 39/747 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- CNTN4 | c.175_176del p.H59Yfs*11 | Frame Shift Del (DEL) | VAF 10/162 reads (6%) | called by mutect2, pindel
- COL20A1 | c.1658G>T p.R553M | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2
- COL6A3 | c.7824C>G p.D2608E | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2
- CPEB4 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CR2 | c.*18+2T>C | Splice Site (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- CRHR1 | c.565T>G p.S189A (on ENST00000398285 / NM_001145146.2; = p.S160A on NM_004382.5) | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- DMD | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DOCK2 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2
- DYNC1I1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- EEFSEC | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 31/344 reads (9%) | called by muse, mutect2
- EIF4G1 | c.2294G>T p.R765L (on ENST00000346169 / NM_198241.3; = p.R570L on NM_004953.5) | Missense Mutation (SNP) | VAF 31/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EYA1 | c.1712T>C p.F571S | Missense Mutation (SNP) | VAF 50/765 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAT3 | c.2486C>A p.P829Q | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT4 | c.7885C>A p.L2629M | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FOXB2 | c.1046A>T p.K349M | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- FTL | c.337_343del p.D113Mfs*21 | Frame Shift Del (DEL) | VAF 67/791 reads (8%) | called by mutect2, pindel
- GJB7 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK3 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 34/694 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGF2BP3 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2
- IGSF6 | c.253A>T p.S85C | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- IPO7 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- KCNIP3 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1074G>T p.K358N | Missense Mutation (SNP) | VAF 37/616 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- KCTD12 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2
- KCTD8 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 22/543 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- KRTAP12-4 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.957); called by muse, mutect2
- LKAAEAR1 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2
- LRP1B | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- MAST4 | c.4471G>A p.E1491K (on ENST00000403625 / NM_001164664.2; = p.E1302K on NM_015183.3) | Missense Mutation (SNP) | VAF 15/430 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MICAL3 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MRGPRE | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- MROH2B | c.1319A>T p.D440V | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- MTMR12 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2
- MYL3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.009); called by muse, mutect2
- NEB | c.14665G>A p.D4889N | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2
- NEDD1 | c.1821C>G p.C607W | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- NLGN4Y | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2
- NOC4L | c.1431+1G>T p.X477_splice | Splice Site (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- NRDE2 | c.40C>G p.P14A | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- NRIP1 | c.387T>A p.D129E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.05); called by muse, mutect2
- OBSCN | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 39/776 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.993); called by muse, mutect2
- OLFML2B | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2
- OR2G3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2
- PCDHA2 | c.980C>G p.T327S | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.028); called by muse, mutect2
- PCNT | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 26/458 reads (6%) | called by muse, mutect2
- PIFO | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.382); called by muse, mutect2
- PLAGL2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 46/675 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXNB2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PROM1 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- PRR12 | c.148G>T p.E50* (on ENST00000615927; = p.E871* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 22/379 reads (6%) | called by muse, mutect2
- RGS7 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RYR2 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SCN7A | c.4653G>T p.M1551I | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SHROOM1 | c.2260C>T p.R754W (on ENST00000378679 / NM_001172700.2; = p.R749W on NM_133456.2) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC25A20 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLC48A1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- SLC7A9 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 50/466 reads (11%) | called by muse, mutect2
- SLIT3 | c.3421C>A p.P1141T | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2
- SNX25 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPDYE5 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- STARD9 | c.11000C>T p.S3667L | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2
- STAT5B | c.1605G>C p.Q535H | Missense Mutation (SNP) | VAF 42/870 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2
- TAF15 | c.1415G>T p.G472V (on ENST00000605844 / NM_139215.3; = p.G469V on NM_003487.4) | Missense Mutation (SNP) | VAF 24/467 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2
- TAF4 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- TBX5 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 29/738 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEX14 | c.1785G>T p.R595S (on ENST00000240361 / NM_001201457.2; = p.R589S on NM_031272.5) | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2
- TLR7 | c.2557C>T p.L853F | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TOMM40L | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2
- TRBV7-1 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRIM64C | c.1088C>G p.T363R | Missense Mutation (SNP) | VAF 12/351 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TTBK1 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 32/337 reads (9%) | called by muse, mutect2
- TTC7B | c.1459+1G>T p.X487_splice | Splice Site (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- TUT7 | c.2523G>A p.M841I | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZFP30 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF530 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.037); called by muse, mutect2
- ZNF875 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2
- AIRE | c.378C>A p.P126= | Silent (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- ANKRD26 | c.795C>T p.D265= | Silent (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- APOBEC1 | c.666C>A p.I222= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2
- ARHGEF11 | c.1038A>T p.A346= | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- ASTN2 | c.564C>A p.A188= | Silent (SNP) | VAF 17/348 reads (5%) | called by muse, mutect2
- CACNA1A | c.2617C>A p.R873= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as COSV64197078; called by muse, mutect2
- CALHM1 | c.114C>T p.F38= | Silent (SNP) | VAF 41/563 reads (7%) | catalogued as rs921351354; called by muse, mutect2
- CCDC106 | c.795C>G p.L265= | Silent (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- CCDC168 | c.16341A>G p.A5447= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- CDH2 | c.2625C>T p.S875= | Silent (SNP) | VAF 26/483 reads (5%) | called by muse, mutect2
- CEP170 | c.1584C>T p.D528= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- CEP350 | c.7419G>A p.V2473= | Silent (SNP) | VAF 9/160 reads (6%) | catalogued as rs1468140063; called by muse, mutect2
- COL5A1 | c.5346C>A p.I1782= | Silent (SNP) | VAF 23/415 reads (6%) | called by muse, mutect2
- CRP | c.618G>T p.R206= | Silent (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- DPP3 | c.1308C>T p.I436= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- DTX3L | c.36C>T p.L12= | Silent (SNP) | VAF 14/380 reads (4%) | catalogued as rs1187052147, COSV56145079, COSV99950077; called by muse, mutect2
- ESX1 | c.666C>G p.A222= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- GABRG2 | c.1353C>A p.G451= (on ENST00000361925 / NM_001375343.1; = p.G411= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/494 reads (6%) | called by muse, mutect2
- GIT1 | c.180G>T p.L60= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- IDE | c.2430C>A p.L810= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- INVS | c.1974C>T p.S658= | Silent (SNP) | VAF 49/798 reads (6%) | called by muse, mutect2
- IRGQ | c.1113G>A p.E371= | Silent (SNP) | VAF 30/497 reads (6%) | catalogued as COSV60671298; called by muse, mutect2
- ISCA2 | c.345C>T p.F115= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs143682573; called by muse, mutect2
- LSG1 | c.69G>T p.R23= | Silent (SNP) | VAF 44/418 reads (11%) | called by muse, mutect2, varscan2
- MACROH2A1 | c.639G>A p.E213= (on ENST00000510038; = p.E212= on NM_004893.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- MVB12A | c.423C>T p.G141= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as rs890683307, COSV57678778; called by muse, mutect2
- NALCN | c.1233C>T p.F411= | Silent (SNP) | VAF 24/285 reads (8%) | catalogued as COSV99213761; called by muse, mutect2
- NRN1 | c.315C>A p.G105= | Silent (SNP) | VAF 32/582 reads (5%) | called by muse, mutect2
- OR2J3 | c.411C>T p.V137= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- SEC24D | c.1851C>G p.V617= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- SH3BP2 | c.1011C>T p.F337= | Silent (SNP) | VAF 19/536 reads (4%) | called by muse, mutect2
- SLC24A1 | c.480A>G p.R160= | Silent (SNP) | VAF 29/633 reads (5%) | catalogued as rs1318741004; called by muse, mutect2
- SLC26A2 | c.1425C>T p.F475= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- SNUPN | c.24G>A p.L8= | Silent (SNP) | VAF 18/314 reads (6%) | catalogued as rs1352454511; called by muse, mutect2
- STRA6 | c.1317G>A p.Q439= | Silent (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- TAF15 | c.1416A>G p.G472= (on ENST00000605844 / NM_139215.3; = p.G469= on NM_003487.4) | Silent (SNP) | VAF 25/475 reads (5%) | called by muse, mutect2
- TET2 | c.5673G>A p.R1891= | Silent (SNP) | VAF 27/569 reads (5%) | called by muse, mutect2
- TK1 | c.522G>C p.V174= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- TOGARAM1 | c.3054C>T p.I1018= | Silent (SNP) | VAF 11/256 reads (4%) | catalogued as COSV63894343; called by muse, mutect2
- TRIM29 | c.399G>A p.S133= | Silent (SNP) | VAF 32/558 reads (6%) | catalogued as rs772848985, COSV59278979, COSV59279533; called by muse, mutect2
- UPF3A | c.1191G>T p.G397= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- ZNF536 | c.717C>A p.T239= | Silent (SNP) | VAF 15/246 reads (6%) | called by muse, mutect2
- ABCB4 | chr7:87401925 A>G | 3'Flank (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- AC005865.1 | n.1732G>A | RNA (SNP) | VAF 36/329 reads (11%) | catalogued as rs752130748; called by muse, mutect2, varscan2
- AC024940.1 | n.2558G>T | RNA (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ACAD9 | c.*231G>C | 3'UTR (SNP) | VAF 68/836 reads (8%) | called by muse, mutect2
- ACBD5 | chr10:27240700 G>C | 5'Flank (SNP) | VAF 16/445 reads (4%) | called by muse, mutect2
- AL136982.4 | n.556A>T | RNA (SNP) | VAF 28/983 reads (3%) | called by muse, mutect2
- AOAH | c.*137T>C | 3'UTR (SNP) | VAF 22/375 reads (6%) | catalogued as rs768594140; called by muse, mutect2
- C19orf12 | chr19:29700945 G>A | 3'Flank (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- CCNYL2 | n.624-2639G>T | Intron (SNP) | VAF 19/362 reads (5%) | called by muse, mutect2
- FAM83A | c.-310G>A | 5'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- GMPPA | c.854-62G>T | Intron (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- GPX4 | c.-15C>A | 5'UTR (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- HDAC8 | c.738-9897G>A | Intron (SNP) | VAF 16/119 reads (13%) | catalogued as rs1555999530; called by muse, mutect2, varscan2
- MRGPRG | chr11:3222055 C>T | 5'Flank (SNP) | VAF 23/398 reads (6%) | called by muse, mutect2
- NACA4P | n.673G>T | RNA (SNP) | VAF 26/570 reads (5%) | called by muse, mutect2
- PHF12 | c.2359+29C>T | Intron (SNP) | VAF 38/586 reads (6%) | called by muse, mutect2
- PRCP | chr11:82900815 C>A | 5'Flank (SNP) | VAF 20/357 reads (6%) | catalogued as rs972353080; called by muse, mutect2
- PRM2 | c.*25C>T | 3'UTR (SNP) | VAF 20/474 reads (4%) | catalogued as rs1306028283, COSV54113958; called by muse, mutect2
- RUSC1 | c.-86-281C>T | Intron (SNP) | VAF 14/247 reads (6%) | catalogued as COSV52740082, COSV99429874, COSV99430304; called by muse, mutect2
- TBX15 | c.1025-5423A>T | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- UNC5A | c.722-660C>T | Intron (SNP) | VAF 8/101 reads (8%) | catalogued as rs1363551828, COSV56172693; called by muse, mutect2
- VKORC1 | c.173+219G>T | Intron (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- ZNF451 | c.186+2230C>T | Intron (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- ZSWIM8 | c.-181G>A | 5'UTR (SNP) | VAF 20/566 reads (4%) | catalogued as COSV65708644; called by muse, mutect2
